Somatic mutation profile of tumor specimen 0DRO49 from CCDI case PBCBFW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 4.0 years (1,453 days).
Specimen 0DRO49: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd5b648-1e1c-4701-9f20-7511a2b42028.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRO3G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5067d7e-f8b0-4c5d-b120-9361514e1ff4

The open-access MAF lists 76 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Intron 9, 3'UTR 3, Splice Site 2, Splice Region 2, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 319/446 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD26 | c.2930G>C p.R977P | Missense Mutation (SNP) | VAF 185/2120 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV65774563; called by muse, mutect2
- C20orf194 | c.3421+1G>A p.X1141_splice | Splice Site (SNP) | VAF 167/305 reads (55%) | catalogued as COSV52690812; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DYNC2H1 | c.12581C>T p.S4194F | Missense Mutation (SNP) | VAF 84/822 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886042136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESRRG | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 151/1118 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs1349900590, COSV100752977; called by muse, mutect2, varscan2
- FREM1 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 297/566 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1563988293; called by muse, mutect2, varscan2
- FREM2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 90/691 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.55); catalogued as rs776551518, COSV99748118; called by muse, mutect2, varscan2
- GRM8 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 288/1016 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV100280618; called by muse, mutect2, varscan2
- HMX1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754542646; called by muse, mutect2, varscan2
- LTN1 | c.3152G>T p.C1051F | Missense Mutation (SNP) | VAF 575/1216 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.107); catalogued as rs1234882435; called by muse, mutect2, varscan2
- PCDH15 | c.4915G>A p.D1639N (on ENST00000644397 / NM_001354429.2; = p.D1581N on NM_001142771.2) | Missense Mutation (SNP) | VAF 89/1577 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs759165641; called by muse, mutect2
- PCDHA8 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 194/525 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs782703557, COSV65325687; called by muse, mutect2, varscan2
- RYR2 | c.6312G>C p.K2104N | Missense Mutation (SNP) | VAF 81/671 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63657530, COSV63686601; called by muse, mutect2, varscan2
- TLDC2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 78/608 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375544929; called by muse, varscan2
- ZNF341 | c.1840C>A p.H614N (on ENST00000375200 / NM_001282935.1; = p.H607N on NM_032819.4) | Missense Mutation (SNP) | VAF 78/451 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); catalogued as COSV61008061; called by muse, mutect2, varscan2
- ACKR2 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADAM22 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 108/1251 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- AFP | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 144/1474 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANPEP | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 99/2879 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ARFGEF3 | c.4714T>G p.C1572G | Missense Mutation (SNP) | VAF 71/611 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BCOR | c.2058_2088del p.N688Qfs*17 | Frame Shift Del (DEL) | VAF 85/153 reads (56%) | called by mutect2, varscan2
- CARMIL1 | c.2505-1G>T p.X835_splice | Splice Site (SNP) | VAF 74/710 reads (10%) | called by mutect2, varscan2
- CCDC88C | c.4510A>T p.T1504S | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CHST7 | c.134_135insT p.G47Rfs*76 | Frame Shift Ins (INS) | VAF 51/68 reads (75%) | called by mutect2, varscan2
- ENO1 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 35/554 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- GPR149 | c.2062T>A p.S688T | Missense Mutation (SNP) | VAF 37/1437 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.091); called by muse, mutect2
- HIVEP2 | c.2243A>C p.E748A | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.257); called by muse, mutect2
- HSPG2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 136/361 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MAP3K1 | c.1396A>C p.K466Q | Missense Mutation (SNP) | VAF 112/941 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MDN1 | c.10009A>G p.I3337V | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- MUC12 | c.5354C>T p.T1785I (on ENST00000379442; = p.T1642I on NM_001164462.1) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- NBR1 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 93/938 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); called by muse, mutect2
- NELL1 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 77/606 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR3A3 | c.877A>T p.M293L | Missense Mutation (SNP) | VAF 269/412 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHGA9 | c.2232T>G p.D744E | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PLCE1 | c.6856G>T p.E2286* | Nonsense Mutation (SNP) | VAF 112/991 reads (11%) | called by muse, mutect2, varscan2
- PTOV1 | c.1239+6G>T | Splice Region (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- RASL11B | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 65/521 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STARD13 | c.3226G>A p.G1076S (on ENST00000336934 / NM_001243476.3; = p.G958S on NM_052851.3) | Missense Mutation (SNP) | VAF 92/897 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT3 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); called by muse, varscan2
- SYT3 | c.675G>A p.R225= | Splice Region (SNP) | VAF 26/190 reads (14%) | called by muse, varscan2
- WDR87 | c.3237C>A p.S1079R | Missense Mutation (SNP) | VAF 61/592 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZFPM2 | c.2261C>G p.P754R | Missense Mutation (SNP) | VAF 272/1010 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by mutect2, varscan2
- ZSWIM1 | c.69G>C p.W23C | Missense Mutation (SNP) | VAF 92/867 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANKRD26 | c.2931G>C p.R977= | Silent (SNP) | VAF 184/2111 reads (9%) | called by muse, mutect2
- FLG | c.7578C>T p.G2526= | Silent (SNP) | VAF 59/148 reads (40%) | called by muse, mutect2, varscan2
- FRAS1 | c.10572G>A p.R3524= | Silent (SNP) | VAF 117/1016 reads (12%) | catalogued as rs1010114521; called by muse, mutect2, varscan2
- GOLGA6L10 | c.729A>G p.L243= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1404051955; called by muse, varscan2
- GRIP2 | c.2415C>T p.N805= (on ENST00000619221; = p.N708= on NM_001080423.4) | Silent (SNP) | VAF 53/426 reads (12%) | catalogued as rs766697549; called by muse, mutect2, varscan2
- HOOK1 | c.997C>T p.L333= | Silent (SNP) | VAF 176/1723 reads (10%) | called by muse, mutect2, varscan2
- HSD11B2 | c.9C>T p.R3= | Silent (SNP) | VAF 19/213 reads (9%) | catalogued as rs1239367951; called by muse, mutect2
- HTRA1 | c.558C>T p.I186= | Silent (SNP) | VAF 77/486 reads (16%) | catalogued as COSV100934842; called by muse, mutect2, varscan2
- KIF7 | c.1047C>T p.I349= | Silent (SNP) | VAF 44/1132 reads (4%) | called by muse, mutect2
- KIF7 | c.855C>A p.V285= | Silent (SNP) | VAF 37/906 reads (4%) | called by muse, mutect2
- KIF7 | c.663C>T p.F221= | Silent (SNP) | VAF 49/1172 reads (4%) | called by muse, mutect2
- LSM11 | c.1041C>T p.F347= | Silent (SNP) | VAF 220/538 reads (41%) | called by muse, varscan2
- MUC17 | c.5763T>A p.P1921= | Silent (SNP) | VAF 60/714 reads (8%) | catalogued as COSV60286842; called by muse, mutect2
- PCDHGB5 | c.2235T>G p.P745= | Silent (SNP) | VAF 45/424 reads (11%) | called by muse, mutect2, varscan2
- SLX4 | c.1599C>A p.G533= | Silent (SNP) | VAF 89/327 reads (27%) | called by mutect2, varscan2
- SPIN2B | c.510T>G p.P170= | Silent (SNP) | VAF 166/290 reads (57%) | called by muse, mutect2, varscan2
- VASP | c.312C>A p.A104= | Silent (SNP) | VAF 55/295 reads (19%) | called by mutect2, varscan2
- ZNF534 | c.1272A>G p.K424= (on ENST00000332323 / NM_001143939.3; = p.K411= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/465 reads (8%) | called by muse, mutect2
- ABCA5 | c.4536-90T>C | Intron (SNP) | VAF 17/110 reads (15%) | catalogued as rs1340529659; called by muse, mutect2, varscan2
- AC107023.1 | n.26-9261G>A | Intron (SNP) | VAF 221/618 reads (36%) | catalogued as rs577088505; called by muse, mutect2, varscan2
- C16orf90 | c.*72C>T | 3'UTR (SNP) | VAF 14/100 reads (14%) | catalogued as rs576452497; called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- CASP4 | c.782-16G>A | Intron (SNP) | VAF 25/230 reads (11%) | catalogued as rs763727836; called by muse, mutect2, varscan2
- CCDC150 | c.-4A>T | 5'UTR (SNP) | VAF 43/758 reads (6%) | called by muse, mutect2
- GNB5 | c.127-67C>G | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- MADD | c.*55G>C | 3'UTR (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- MNX1 | c.691+674C>G | Intron (SNP) | VAF 104/1616 reads (6%) | called by muse, mutect2
- NAT10 | c.2812-93A>G | Intron (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- NCL | c.1290-37G>A | Intron (SNP) | VAF 50/653 reads (8%) | catalogued as rs1051699538; called by muse, mutect2
- TRIM5 | c.896-103C>A | Intron (SNP) | VAF 59/571 reads (10%) | called by muse, mutect2, varscan2
- ZNF695 | c.*53A>G | 3'UTR (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
